Gene-level copy-number profile of tumor specimen HTMCP-03-06-02089-01A from CGCI case HTMCP-03-06-02089, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 41.8 years (15,269 days).
Specimen HTMCP-03-06-02089-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1d0a046c-3ec6-4775-ae41-f6a275fac793.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02089-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/6eda7604-8e2d-4bba-b87e-4ef09e8a62b4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2; copy number 2: 967; copy number 3: 11,559; copy number 4: 32,010; copy number 5: 7,304; copy number 6: 4,766; copy number 7: 1,444; copy number 8: 72; copy number 9: 8; copy number 10: 32; copy number 11: 66; copy number 12: 64; copy number 13: 1; copy number 14: 76; copy number 16: 21.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,208,082–141,208,376, 1 gene (within-gene range 0–4): RPS16P3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 235 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:60,281,444–60,546,660, 1 gene, copy number 14: AC244258.1.
- chr7:38,239,580–38,249,572, 1 gene, copy number 11: TRGC2.
- chr7:38,257,879–38,330,935, 11 genes, copy number 11 (within-gene range 6–11): TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, AC006033.2, TRGV8.
- chr9:138,129,399–138,143,864, 2 genes, copy number 11: AL591424.1, IL9RP1.
- chr20:30,214,765–36,863,538, 220 genes, copy number 9–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
